Somatic mutation profile of tumor specimen TARGET-10-PATCKV-09A (aliquot TARGET-10-PATCKV-09A-01D) from TARGET case TARGET-10-PATCKV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,266 days).
Specimen TARGET-10-PATCKV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42de4641-162f-406e-b77d-d7e3a753606c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCKV-10A (Blood Derived Normal), aliquot TARGET-10-PATCKV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1560191d-ddcb-4ce9-a570-1b812bed9e61

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, RNA 2, 5'Flank 1, In Frame Ins 1, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs557075212, COSV53912260; called by muse, mutect2, varscan2
- BRPF1 | c.1213T>A p.C405S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57405668; called by muse, mutect2, varscan2
- CCBE1 | c.1061A>C p.E354A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV101232897, COSV67950262; called by muse, mutect2, varscan2
- DSCC1 | c.458A>C p.Q153P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58087378, COSV58088525; called by muse, mutect2, varscan2
- ERBB3 | c.3997C>T p.L1333F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV57256030; called by muse, mutect2, varscan2
- FIP1L1 | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV60997353; called by muse, mutect2, varscan2
- IL7R | c.728_729insCCAGCGGTGTAC p.L243_T244insQRCT | In Frame Ins (INS) | VAF 17/90 reads (19%) | catalogued as COSV57406755, COSV57406894; called by mutect2, pindel*, varscan2
- LAMA5 | c.4267G>A p.A1423T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs149794678, COSV53362355; called by muse, mutect2, varscan2
- LRP2 | c.9362G>T p.G3121V | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55558215; called by muse, mutect2, varscan2
- LYRM7 | c.315A>C p.*105Cext*3 | Nonstop Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV65086503; called by muse, mutect2, varscan2
- MSH4 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763754874, COSV54204840, COSV99591272; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- OR4X2 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56583732; called by muse, mutect2, varscan2
- PCDHB12 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.124); catalogued as COSV53397685; called by muse, mutect2, varscan2
- PLSCR4 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as rs754225026, COSV61608191; called by muse, mutect2, varscan2
- SEC16A | c.1997T>C p.M666T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51530465; called by muse, mutect2, varscan2
- TFAP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52597990; called by muse, mutect2, varscan2
- TRIM42 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs749762555, COSV53884039; called by muse, mutect2, varscan2
- CRYBG3 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- NOTCH1 | c.7525T>C p.F2509L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOA | c.3408G>T p.W1136C (on ENST00000286149; = p.W1122C on NM_144672.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.263); called by muse, mutect2
- SRSF3 | c.256dup p.R86Kfs*3 | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- ADAMTS19 | c.1656G>A p.P552= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as rs200248424, COSV50759838; called by muse, mutect2, varscan2
- ANKRD35 | c.441C>T p.D147= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs143388227; called by muse, mutect2, varscan2
- IGSF21 | c.219C>T p.F73= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- KMT2E | c.5259T>C p.S1753= | Silent (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- NCOR2 | c.1398C>T p.C466= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs141727061, COSV62303866; called by muse, mutect2, varscan2
- RBMS2 | c.39T>G p.T13= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- AC006971.1 | n.4250C>A | RNA (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- FAM205BP | n.356C>A | RNA (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- FBLN5 | c.*83_*84insTAAAGCCCGTC | 3'UTR (INS) | VAF 9/30 reads (30%) | called by mutect2, varscan2
- HIPK1 | chr1:113929430 T>C | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- NCAM1 | c.1826-69C>T | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs373035991; called by muse, mutect2, varscan2
